Somatic mutation profile of tumor specimen C3N-02152-04 (aliquot CPT0213780007) from CPTAC case C3N-02152, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.7 years (22,161 days).
Specimen C3N-02152-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8967719e-6e5e-4459-8856-bdcb2aa5de21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02152-71 (Blood Derived Normal), aliquot CPT0213870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad3406ba-ef5a-43c6-a4bc-fc5006f3e876

The open-access MAF lists 1,538 somatic variants for this specimen: 1,060 protein-altering or splice-affecting, 291 silent, 187 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 899, Silent 291, Intron 100, Nonsense Mutation 81, Splice Site 39, RNA 31, Frame Shift Del 20, 5'UTR 19, 3'UTR 18, Splice Region 13, 5'Flank 10, 3'Flank 9.

Variants (750 of 1,538; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>T p.X51_splice | Splice Site (SNP) | VAF 54/447 reads (12%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 177/404 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- OLFML2B | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224950; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 76/247 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 71/521 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs986222121; called by muse, mutect2, varscan2
- ABCA9 | c.2342T>G p.I781R | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1285542886; called by muse, mutect2, varscan2
- ABCC2 | c.4301G>T p.G1434V | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376276952; called by muse, mutect2, varscan2
- ABTB1 | c.764G>T p.G255V (on ENST00000232744 / NM_172027.3; = p.G113V on NM_032548.3) | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1233505697; called by muse, mutect2, varscan2
- ACP7 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs762535102; called by muse, mutect2
- ADAMTS2 | c.2821C>A p.R941S | Missense Mutation (SNP) | VAF 97/619 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as rs937744996, COSV52365650, COSV52367097; called by muse, mutect2, varscan2
- ADAMTS2 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 98/402 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51083639; called by muse, mutect2, varscan2
- ADAMTS2 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 68/513 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51109349; called by muse, mutect2, varscan2
- ADCY8 | c.2353C>G p.R785G | Missense Mutation (SNP) | VAF 49/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53933309, COSV99654063; called by muse, mutect2, varscan2
- ADNP2 | c.950del p.G317Efs*15 | Frame Shift Del (DEL) | VAF 37/133 reads (28%) | catalogued as COSV51537697; called by mutect2, pindel, varscan2
- AEBP2 | c.1433C>G p.S478* | Nonsense Mutation (SNP) | VAF 56/306 reads (18%) | catalogued as COSV99857341; called by muse, mutect2, varscan2
- AGK | c.160A>G p.I54V | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1352085810; called by muse, mutect2, varscan2
- AHNAK2 | c.8806G>T p.D2936Y | Missense Mutation (SNP) | VAF 56/559 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752819329, COSV60911971; called by muse, mutect2, varscan2
- AKAP3 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs757778089; called by muse, mutect2, varscan2
- AMPD1 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100815220; called by muse, mutect2, varscan2
- ANK3 | c.13042G>T p.G4348W (on ENST00000280772 / NM_001320874.2; = p.G972W on NM_001149.3) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV55054465; called by muse, mutect2, varscan2
- ANO1 | c.2349C>A p.I783= | Splice Region (SNP) | VAF 19/134 reads (14%) | catalogued as COSV62449147; called by muse, mutect2, varscan2
- AP000471.1 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 98/544 reads (18%) | catalogued as COSV52448827; called by muse, mutect2, varscan2
- ARHGEF17 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1357429453; called by muse, mutect2, varscan2
- ASIC5 | c.1382T>C p.I461T | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs371946061; called by muse, mutect2, varscan2
- ATP13A1 | c.2798G>C p.R933P | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs749319067, COSV52282597; called by muse, mutect2, varscan2
- ATP13A2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs144898239; called by muse, varscan2
- ATP4A | c.1777G>T p.G593C | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52870316; called by muse, mutect2, varscan2
- ATRN | c.3475C>G p.L1159V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53532280; called by muse, mutect2, varscan2
- BTN1A1 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 102/387 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV55069598; called by muse, mutect2, varscan2
- C12orf50 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53894750, COSV53894777; called by muse, mutect2
- C1orf74 | c.656A>T p.Y219F | Missense Mutation (SNP) | VAF 68/458 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV50551508; called by muse, mutect2, varscan2
- C6orf118 | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV57816253; called by muse, mutect2, varscan2
- C8A | c.731A>T p.K244M | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs780440275; called by muse, mutect2, varscan2
- CACNA1H | c.6772G>A p.A2258T | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV52353112; called by muse, mutect2
- CALHM1 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs760631503; called by muse, mutect2, varscan2
- CD1C | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63807005, COSV63807643; called by muse, mutect2
- CDC14A | c.1785A>T p.*595Yext*41 | Nonstop Mutation (SNP) | VAF 28/149 reads (19%) | catalogued as COSV100324466; called by muse, mutect2, varscan2
- CDH12 | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 29/307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66396454; called by muse, mutect2, varscan2
- CDH12 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV66447674; called by muse, mutect2, varscan2
- CDH23 | c.7225G>T p.E2409* | Nonsense Mutation (SNP) | VAF 42/205 reads (20%) | catalogued as rs1204553210; called by muse, mutect2, varscan2
- CDH24 | c.2210C>A p.P737H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.869); catalogued as rs1458768289; called by mutect2, varscan2
- CDK5RAP2 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 36/184 reads (20%) | catalogued as COSV62573958; called by muse, mutect2, varscan2
- CDON | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 122/388 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.608); catalogued as COSV55001380; called by muse, mutect2, varscan2
- CFAP46 | c.6424G>T p.A2142S | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.802); catalogued as rs747291483; called by muse, mutect2
- CFHR5 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 23/271 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs769456068, COSV56830917; called by muse, mutect2
- CHST3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs903606184; called by muse, mutect2, varscan2
- CHSY3 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV59284462; called by muse, mutect2, varscan2
- CLK4 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as COSV100309095; called by muse, mutect2, varscan2
- CLPTM1L | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1321366460, COSV100306806; called by muse, mutect2, varscan2
- CNTN6 | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.81); catalogued as COSV63173298; called by mutect2, varscan2
- CNTNAP3B | c.2028C>A p.C676* | Nonsense Mutation (SNP) | VAF 55/494 reads (11%) | catalogued as rs2935317; called by muse, mutect2, varscan2
- COL11A1 | c.3337C>A p.P1113T | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100615541; called by muse, mutect2, varscan2
- COL1A2 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 133/569 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV51958790; called by muse, mutect2, varscan2
- COL20A1 | c.2213C>A p.T738K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs77576225; called by muse, mutect2, varscan2
- COL22A1 | c.1732G>C p.G578R | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57346570; called by muse, mutect2
- COL22A1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277863, COSV99079042; called by muse, mutect2
- COL4A6 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 101/165 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318938407, COSV57875041; called by muse, mutect2, varscan2
- COL5A1 | c.2809G>T p.G937* | Nonsense Mutation (SNP) | VAF 50/376 reads (13%) | catalogued as COSV65675309; called by muse, mutect2, varscan2
- COP1 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as rs201943014; called by muse, mutect2
- COQ7 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100430574; called by muse, mutect2, varscan2
- CPEB1 | c.936G>T p.K312N (on ENST00000617958; = p.K252N on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); catalogued as rs375007947; called by muse, mutect2, varscan2
- CPS1 | c.2678G>T p.G893V | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs760851899; called by muse, mutect2, varscan2
- CR2 | c.307A>G p.R103G | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV65508481; called by muse, mutect2, varscan2
- CRACD | c.2768C>A p.P923H | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99949141; called by muse, mutect2, varscan2
- CRISPLD1 | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV51546331; called by muse, mutect2, varscan2
- CRY1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99150489; called by muse, mutect2, varscan2
- CRY2 | c.1682G>T p.R561L | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV69889216; called by muse, mutect2, varscan2
- CSMD1 | c.7372T>A p.Y2458N (on ENST00000520002; = p.Y2457N on NM_033225.6) | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs778714739; called by muse, mutect2, varscan2
- CTNNA2 | c.2575-1G>T p.X859_splice (on ENST00000402739 / NM_001282597.3; = p.X811_splice on NM_004389.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV58131567; called by muse, mutect2, varscan2
- CTTNBP2 | c.2528G>T p.G843V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50389159; called by muse, mutect2, varscan2
- CYTH3 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63437551; called by muse, mutect2, varscan2
- DAPK1 | c.3373G>T p.V1125L | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV63788843; called by muse, mutect2, varscan2
- DCDC1 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV60833754; called by muse, mutect2
- DGAT2L6 | c.267G>A p.K89= | Splice Region (SNP) | VAF 70/118 reads (59%) | catalogued as rs1331831330; called by muse, mutect2, varscan2
- DGKB | c.1417G>T p.G473* | Nonsense Mutation (SNP) | VAF 51/187 reads (27%) | catalogued as COSV51802497; called by muse, mutect2, varscan2
- DGKI | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 81/243 reads (33%) | catalogued as COSV99934968; called by muse, mutect2, varscan2
- DKK2 | c.564C>A p.D188E | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99568489; called by muse, mutect2, varscan2
- DMBT1 | c.5593G>T p.G1865C (on ENST00000338354 / NM_001377530.1; = p.G1108C on NM_004406.3) | Missense Mutation (SNP) | VAF 100/457 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353893; called by muse, mutect2, varscan2
- DMRTA2 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs904993271; called by muse, mutect2, varscan2
- DNAH11 | c.12266C>A p.A4089D | Missense Mutation (SNP) | VAF 89/421 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV60941498; called by muse, mutect2, varscan2
- DNAH14 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 134/334 reads (40%) | PolyPhen benign (0.003); catalogued as rs775759618; called by muse, mutect2, varscan2
- DNAH5 | c.9898-1G>C p.X3300_splice | Splice Site (SNP) | VAF 90/427 reads (21%) | catalogued as COSV54206379; called by muse, mutect2, varscan2
- DNAH8 | c.9926G>T p.G3309V | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as COSV100546942; called by muse, mutect2, varscan2
- DNAH9 | c.8543A>T p.Q2848L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52335735; called by muse, mutect2, varscan2
- DOCK2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs764590955, COSV99913952; called by muse, mutect2, varscan2
- DRP2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as COSV65811223; called by muse, mutect2, varscan2
- DSPP | c.3560G>T p.S1187I | Missense Mutation (SNP) | VAF 115/964 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as CD111501; called by muse, mutect2, varscan2
- DYNC1I1 | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17852086; called by muse, mutect2, varscan2
- ECD | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs1451948944; called by muse, mutect2
- EGR1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV99525390; called by muse, mutect2, varscan2
- ENAM | c.2633G>A p.S878N | Missense Mutation (SNP) | VAF 130/401 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as rs759731409; called by muse, mutect2, varscan2
- ENPP2 | c.2131+1G>T p.X711_splice (on ENST00000075322 / NM_001040092.3; = p.X763_splice on NM_006209.5) | Splice Site (SNP) | VAF 31/115 reads (27%) | catalogued as rs988184026, COSV50012594, COSV50023704; called by muse, varscan2
- ENPP2 | c.2107G>T p.V703F (on ENST00000075322 / NM_001040092.3; = p.V755F on NM_006209.5) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV50009866; called by muse, varscan2
- EPHA5 | c.2004G>T p.K668N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV56635743; called by muse, mutect2, varscan2
- EPHB4 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 72/514 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62267888, COSV62270832; called by muse, mutect2, varscan2
- ERC2 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs746862604; called by muse, mutect2, varscan2
- ERCC6L2 | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1356310380; called by muse, mutect2, varscan2
- ESS2 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV50082238, COSV99324015; called by muse, mutect2, varscan2
- EYS | c.2848T>A p.F950I | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1274173162, COSV65558418; called by muse, mutect2, varscan2
- F9 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 145/230 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs779652204; called by muse, mutect2, varscan2
- FAT4 | c.12910G>C p.G4304R | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58694307; called by muse, mutect2, varscan2
- FBN2 | c.6227C>A p.P2076Q | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV99331157; called by muse, mutect2, varscan2
- FBP2 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564177802; called by muse, mutect2
- FLT4 | c.584C>A p.T195K | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV56098916, COSV99986433; called by muse, mutect2, varscan2
- FLYWCH1 | c.1243G>T p.D415Y (on ENST00000253928 / NM_001308068.2; = p.D414Y on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs368539567; called by muse, mutect2, varscan2
- FMNL3 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs202178648; called by muse, mutect2, varscan2
- FSTL5 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243056662; called by muse, mutect2, varscan2
- GABRA4 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104386252; called by muse, mutect2, varscan2
- GABRD | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66080217; called by muse, mutect2, varscan2
- GALNT17 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); catalogued as rs763825835, COSV61176166, COSV61199369; called by muse, mutect2
- GBP6 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as rs754434114; called by muse, varscan2
- GFRAL | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV61232541; called by muse, mutect2
- GPR4 | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV59916532; called by muse, mutect2, varscan2
- GRIA2 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52397617; called by muse, mutect2
- GRIA4 | c.1848-1G>C p.X616_splice | Splice Site (SNP) | VAF 25/112 reads (22%) | catalogued as COSV99228022; called by muse, mutect2, varscan2
- GRM2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764159304, COSV56585061; called by muse, mutect2, varscan2
- GRM2 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV56584965; called by muse, mutect2, varscan2
- GRM5 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100551183, COSV59603112; called by muse, mutect2, varscan2
- GTF2H4 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as rs61733214; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2149G>T p.G717W | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100736407; called by mutect2, varscan2
- HAO1 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 111/458 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV101113096; called by muse, mutect2, varscan2
- HAS2 | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58267281; called by muse, mutect2, varscan2
- HEATR6 | c.2701G>C p.E901Q | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); catalogued as COSV51748576; called by muse, mutect2, varscan2
- HMX1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.796); catalogued as rs1375529814; called by muse, mutect2, varscan2
- HOXA1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as rs1239001756; called by muse, mutect2, varscan2
- HTR3C | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV59174440; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.7T>A p.W3R | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs752407574; called by muse, mutect2
- IGHV3-74 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.051); catalogued as rs373191611; called by muse, mutect2, varscan2
- INTS3 | c.3032C>G p.S1011W | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55162112; called by muse, mutect2, varscan2
- IP6K3 | c.748C>A p.R250S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV53391529, COSV53392465; called by muse, mutect2, varscan2
- IQCE | c.1587G>T p.Q529H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.564); catalogued as rs1158730650; called by muse, mutect2, varscan2
- IQGAP2 | c.4506-1G>T p.X1502_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99166776; called by muse, mutect2, varscan2
- IRX1 | c.1343C>A p.P448Q | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57361111; called by muse, mutect2, varscan2
- IRX4 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs762652908, COSV51470864, COSV51470906; called by muse, mutect2, varscan2
- ITGB8 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV99752291; called by muse, mutect2
- KASH5 | c.798+8G>A | Splice Region (SNP) | VAF 23/193 reads (12%) | catalogued as rs779780932; called by muse, mutect2, varscan2
- KBTBD11 | c.1103C>A p.A368E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs778206703; called by muse, mutect2, varscan2
- KCNH8 | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100110885; called by muse, mutect2, varscan2
- KCNT1 | c.1392del p.N465Tfs*36 (on ENST00000488444; = p.N484Tfs*36 on NM_020822.3) | Frame Shift Del (DEL) | VAF 25/171 reads (15%) | catalogued as rs770640819; called by mutect2, pindel, varscan2
- KCTD16 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs372522368; called by muse, mutect2, varscan2
- KDM5C | c.1771G>T p.G591* | Nonsense Mutation (SNP) | VAF 70/201 reads (35%) | catalogued as COSV64762637; called by muse, mutect2, varscan2
- KIF5A | c.1867G>T p.G623W | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54051872; called by muse, mutect2, varscan2
- KLF12 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV66569568; called by muse, mutect2, varscan2
- KLF7 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100519091; called by muse, mutect2, varscan2
- KLHDC7A | c.1647G>T p.Q549H | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV68770780; called by muse, mutect2, varscan2
- KLHL20 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52943142; called by muse, mutect2, varscan2
- KPRP | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs193921023, COSV64222883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRTAP24-1 | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs760382015, COSV61089882; called by muse, mutect2, varscan2
- LAMA5 | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1272700375; called by muse, mutect2, varscan2
- LAMC3 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 134/640 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756209261; called by muse, mutect2, varscan2
- LBH | c.229del p.E77Sfs*58 | Frame Shift Del (DEL) | VAF 92/353 reads (26%) | catalogued as COSV68049154, COSV68050168; called by mutect2, pindel, varscan2
- LCE4A | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV59267038; called by muse, mutect2, varscan2
- LCT | c.3524G>A p.R1175K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.233); catalogued as rs1259396941, COSV51551967; called by muse, mutect2, varscan2
- LHFPL1 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1179807908; called by muse, mutect2, varscan2
- LHX2 | c.771C>A p.D257E | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV65318729; called by muse, mutect2, varscan2
- LSM14A | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV70885285; called by muse, mutect2, varscan2
- MARCHF11 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100198111; called by muse, mutect2
- MBD6 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV63073719; called by muse, mutect2, varscan2
- MCPH1 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100765548; called by muse, mutect2, varscan2
- MEOX1 | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59356730; called by muse, mutect2, varscan2
- MET | c.3232G>T p.V1078L | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.988); catalogued as COSV59257115; called by muse, mutect2, varscan2
- MRC1 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 187/758 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs782634590, COSV58889345; called by muse, mutect2, varscan2
- MUC13 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV60701514; called by muse, mutect2, varscan2
- MUC16 | c.36068-1G>T p.X12023_splice | Splice Site (SNP) | VAF 27/144 reads (19%) | catalogued as COSV67488398; called by muse, mutect2, varscan2
- MUC16 | c.2414G>T p.S805I | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as COSV101200642; called by muse, mutect2, varscan2
- MUC7 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 73/522 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.713); catalogued as rs879135475, COSV100512192; called by muse, varscan2
- MYBPC1 | c.1312C>A p.P438T (on ENST00000550270 / NM_206820.2; = p.P463T on NM_002465.4) | Missense Mutation (SNP) | VAF 81/326 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV99053741; called by muse, mutect2, varscan2
- MYH14 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1046817335; called by muse, mutect2, varscan2
- MYLK | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 153/402 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs1407395670, COSV100659312; called by muse, mutect2, varscan2
- MYO18B | c.7010C>T p.T2337I | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1337818419, COSV100125100; called by muse, mutect2, varscan2
- MYO7A | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.448); catalogued as rs1555069582; called by muse, mutect2, varscan2
- NALCN | c.2155C>A p.L719I | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs369811330; called by muse, mutect2, varscan2
- NCAN | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53047718; called by muse, mutect2, varscan2
- NEK8 | c.1892-1G>C p.X631_splice | Splice Site (SNP) | VAF 29/225 reads (13%) | catalogued as COSV99261926; called by muse, mutect2, varscan2
- NF1 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 20/133 reads (15%) | catalogued as COSV100648007; called by muse, mutect2, varscan2
- NFASC | c.3313A>G p.I1105V (on ENST00000339876 / NM_001378329.1; = p.I1034V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/305 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV100363469; called by muse, mutect2, varscan2
- NLRP3 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 60/453 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as rs200590698, COSV100276823; called by muse, mutect2, varscan2
- NLRP4 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.355); catalogued as COSV56709497; called by muse, mutect2, varscan2
- NLRP8 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV52585006, COSV52591140; called by muse, mutect2, varscan2
- NPAS4 | c.1270C>G p.P424A | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100214706; called by muse, mutect2, varscan2
- NPHS1 | c.3167-1G>T p.X1056_splice | Splice Site (SNP) | VAF 43/229 reads (19%) | catalogued as rs1009762900; called by muse, mutect2, varscan2
- NRG3 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV64587531; called by muse, mutect2, varscan2
- OGN | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV52760211, COSV52760272; called by muse, mutect2, varscan2
- OLFML2B | c.1380C>A p.D460E | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54201230; called by muse, mutect2, varscan2
- OR10K1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99194150; called by muse, mutect2, varscan2
- OR10Q1 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57470257; called by muse, mutect2, varscan2
- OR1S1 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 73/259 reads (28%) | catalogued as rs1406919672, COSV100515353, COSV58706707; called by muse, mutect2, varscan2
- OR2M5 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.58); catalogued as rs138582176, COSV63547279; called by muse, mutect2, varscan2
- OR2T4 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 67/663 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1232158316, COSV63543547; called by muse, mutect2, varscan2
- OR4A15 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs767252403, COSV100124387; called by muse, mutect2, varscan2
- OR4C6 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV58602434; called by muse, mutect2, varscan2
- OR4X2 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56583640; called by muse, mutect2, varscan2
- OR51F1 | c.748T>A p.C250S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58581002; called by muse, mutect2, varscan2
- OR52K2 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767786133; called by mutect2, varscan2
- OR5T3 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs1050005712; called by muse, mutect2, varscan2
- OTOG | c.6442G>A p.V2148I | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.2); catalogued as rs1420960073, COSV61130467; called by muse, varscan2
- OTOG | c.7573C>T p.L2525F | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs899122772; called by muse, mutect2, varscan2
- OVGP1 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); catalogued as rs755291577; called by muse, mutect2, varscan2
- PAK1 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV53702332; called by muse, mutect2, varscan2
- PAK5 | c.1293G>T p.Q431H | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62025543; called by muse, mutect2, varscan2
- PCDH1 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54618850; called by muse, mutect2, varscan2
- PCDH15 | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57258717; called by muse, mutect2, varscan2
- PCDHA10 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.152); catalogued as rs782007386; called by muse, mutect2, varscan2
- PCDHA3 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 113/852 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1554122256, COSV63543619; called by muse, mutect2, varscan2
- PCDHA7 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 101/670 reads (15%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.136); catalogued as rs782579390; called by muse, varscan2
- PCDHB3 | c.2340G>T p.E780D | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV50572099; called by muse, mutect2
- PCDHGB3 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as rs758506114; called by muse, mutect2, varscan2
- PCLO | c.2320A>T p.T774S | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV100428988; called by muse, mutect2, varscan2
- PDE1A | c.959G>C p.R320P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59529311; called by muse, mutect2, varscan2
- PDLIM3 | c.422C>T p.A141V (on ENST00000284770 / NM_001257963.1; = p.A308V on NM_014476.6) | Missense Mutation (SNP) | VAF 124/517 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs774383499, COSV52977921, COSV52979964; called by muse, mutect2, varscan2
- PDZRN3 | c.1714G>T p.G572W | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1453478364, COSV104376393; called by muse, mutect2, varscan2
- PGAP1 | c.1447G>C p.V483L | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1329688368; ClinVar: uncertain significance; called by muse, mutect2
- PHF14 | c.1732A>G p.K578E | Missense Mutation (SNP) | VAF 110/426 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV68855781; called by muse, mutect2, varscan2
- PIK3CB | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs375486136; called by muse, mutect2, varscan2
- PIP4K2C | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 68/494 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs139070091; called by muse, mutect2, varscan2
- PKN3 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV52576231; called by muse, mutect2, varscan2
- PLA2G4A | c.1949A>T p.Y650F | Missense Mutation (SNP) | VAF 124/283 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV66553497; called by muse, mutect2, varscan2
- PLCB1 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100571837; called by muse, mutect2, varscan2
- PLCXD3 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV60605512, COSV60608765; called by muse, mutect2, varscan2
- PLEKHG6 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 122/781 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV50614843; called by muse, mutect2, varscan2
- PLPP4 | c.293C>A p.T98K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64829482; called by muse, mutect2, varscan2
- PLXNC1 | c.1688G>C p.R563T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs144918979, COSV51585780; called by muse, mutect2, varscan2
- POGK | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs1248279951, COSV100902427; called by muse, mutect2, varscan2
- POLR1C | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 64/418 reads (15%) | catalogued as rs772375161; called by muse, mutect2, varscan2
- POTEC | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV62804458; called by muse, mutect2, varscan2
- POTEE | c.2539C>A p.R847S | Missense Mutation (SNP) | VAF 231/751 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV58237595; called by muse, mutect2, varscan2
- POU5F1B | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as rs775485125, COSV66966651; called by muse, mutect2
- PPFIA2 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV61050906; called by muse, mutect2
- PRDM9 | c.1546del p.V516* | Frame Shift Del (DEL) | VAF 95/502 reads (19%) | catalogued as rs779742465, COSV57004957, COSV57014674; called by mutect2, pindel, varscan2
- PRR36 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0.04); catalogued as COSV73401709; called by muse, mutect2, varscan2
- PSG6 | c.224T>A p.L75H | Missense Mutation (SNP) | VAF 47/324 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs778559294; called by muse, mutect2, varscan2
- PTCHD4 | c.984G>T p.R328S | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59797416; called by muse, mutect2, varscan2
- PTPRC | c.101-1G>T p.X34_splice | Splice Site (SNP) | VAF 40/303 reads (13%) | catalogued as COSV61409733; called by muse, mutect2, varscan2
- PTPRQ | c.2447G>T p.G816V (on ENST00000616559; = p.G774V on NM_001145026.2) | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.438); catalogued as COSV57034624; called by muse, mutect2, varscan2
- QSOX2 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs1354723363; called by muse, mutect2
- RAB11FIP5 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs528799264, COSV99242422; called by muse, mutect2, varscan2
- RAB29 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 63/497 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373710090; called by muse, mutect2, varscan2
- RAB6D | c.547G>T p.G183* | Nonsense Mutation (SNP) | VAF 36/420 reads (9%) | catalogued as COSV72151704; called by muse, mutect2, varscan2
- RAD17 | c.209C>T p.S70F (on ENST00000380774 / NM_133339.2; = p.S59F on NM_002873.1) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1474871703; called by muse, mutect2, varscan2
- RANBP6 | c.2812G>T p.G938C | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424492; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1632G>C p.S544= | Splice Region (SNP) | VAF 35/131 reads (27%) | catalogued as COSV54584923; called by muse, mutect2, varscan2
- RBM10 | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61308787; called by muse, varscan2
- RBM19 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750278796, COSV55694526; called by muse, mutect2, varscan2
- RFPL2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs762730521, COSV99963971, COSV99964402; called by muse, mutect2, varscan2
- RPS9 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV57189643; called by muse, mutect2, varscan2
- RXRG | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV63231944; called by muse, mutect2
- RYR1 | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 77/415 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62101533; called by muse, mutect2, varscan2
- RYR2 | c.1354G>C p.V452L | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as COSV63701124; called by muse, mutect2
- RYR2 | c.5095C>T p.R1699C | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100773433; called by muse, mutect2, varscan2
- RYR2 | c.8357G>T p.G2786V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs1060500149; called by muse, mutect2
- RYR2 | c.11452G>T p.G3818W | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs867870851; called by muse, mutect2, varscan2
- SAGE1 | c.2409G>C p.M803I | Missense Mutation (SNP) | VAF 145/241 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV61014605; called by muse, mutect2, varscan2
- SASH1 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs759775810; called by muse, mutect2, varscan2
- SBSN | c.535G>T p.G179W | Missense Mutation (SNP) | VAF 109/624 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs879157549, COSV101510089; called by muse, varscan2
- SCIN | c.1298G>C p.R433T (on ENST00000297029 / NM_001112706.3; = p.R186T on NM_033128.3) | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.144); catalogued as COSV51699022; called by muse, mutect2, varscan2
- SCN3A | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 209/590 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51813117; called by muse, mutect2, varscan2
- SCN5A | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.824); catalogued as rs199473167, CM023675, CM100675; called by muse, mutect2, varscan2
- SERPINA3 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 96/377 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as rs929299041, COSV99064551; called by muse, mutect2, varscan2
- SETD4 | c.*30C>G | Splice Region (SNP) | VAF 41/206 reads (20%) | catalogued as COSV59771525; called by muse, mutect2, varscan2
- SGMS1 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100693743; called by muse, mutect2, varscan2
- SLC1A7 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs778796774, COSV100439416; called by muse, mutect2, varscan2
- SLC22A14 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866032740; called by muse, mutect2, varscan2
- SLC25A40 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56696720; called by muse, mutect2, varscan2
- SLC27A6 | c.1565G>T p.R522I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99322731; called by muse, mutect2, varscan2
- SLC28A2 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 54/268 reads (20%) | catalogued as rs988688425; called by muse, mutect2, varscan2
- SLC29A4 | c.1062G>T p.W354C | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs1287162754; called by muse, varscan2
- SLC35F3 | c.1198G>T p.G400C (on ENST00000366617 / NM_001300845.1; = p.G469C on NM_173508.4) | Missense Mutation (SNP) | VAF 154/520 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV100784747; called by muse, mutect2, varscan2
- SLC4A3 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 124/371 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.754); catalogued as COSV56093412; called by muse, mutect2, varscan2
- SLC5A4 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415765103, COSV56669001; called by muse, mutect2, varscan2
- SLC7A10 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 81/350 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV99472403; called by muse, mutect2, varscan2
- SLCO5A1 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV52657917; called by muse, mutect2, varscan2
- SLFN5 | c.1386del p.C463Afs*6 | Frame Shift Del (DEL) | VAF 55/293 reads (19%) | catalogued as COSV55480317; called by mutect2, pindel, varscan2
- SLITRK1 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 64/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1270893720, CD054423, COSV100999989; called by muse, mutect2, varscan2
- SLITRK4 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 157/284 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as rs1556427725; called by muse, mutect2, varscan2
- SMOC2 | c.1216G>T p.V406L (on ENST00000356284 / NM_001166412.2; = p.V417L on NM_022138.3) | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs138048760, COSV62436203; called by muse, mutect2, varscan2
- SMTNL1 | c.1340T>C p.V447A (on ENST00000399154; = p.V484A on NM_001105565.2) | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54703227; called by muse, mutect2, varscan2
- SMYD3 | c.749G>A p.R250Q (on ENST00000490107 / NM_001375962.1; = p.R191Q on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs987211168, COSV104426184; called by muse, mutect2, varscan2
- SNX2 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs1362704067; called by muse, mutect2, varscan2
- SOWAHB | c.2170G>T p.G724* | Nonsense Mutation (SNP) | VAF 34/180 reads (19%) | catalogued as rs777477112, COSV57555188; called by muse, mutect2, varscan2
- SRRM4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs375268699; called by muse, mutect2, varscan2
- ST8SIA6 | c.738C>A p.N246K | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.056); catalogued as rs1162988534; called by muse, mutect2, varscan2
- SUZ12 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV59503952; called by muse, mutect2, varscan2
- SYCP1 | c.2774G>T p.C925F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV101051128; called by muse, varscan2
- SYNE1 | c.8142G>T p.W2714C (on ENST00000367255 / NM_182961.4; = p.W2721C on NM_033071.3) | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54966643; called by muse, mutect2, varscan2
- TAFA4 | c.320T>C p.M107T | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55135997; called by muse, mutect2, varscan2
- TAS2R1 | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 26/156 reads (17%) | catalogued as rs866622597; called by muse, mutect2, varscan2
- TBX18 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100858505; called by muse, mutect2, varscan2
- TDRD1 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV52588148; called by muse, mutect2, varscan2
- TEKT2 | c.851A>T p.K284M | Missense Mutation (SNP) | VAF 84/501 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99255397; called by muse, mutect2, varscan2
- TENM4 | c.7730G>T p.G2577V | Missense Mutation (SNP) | VAF 96/309 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565317588; called by muse, mutect2, varscan2
- TENM4 | c.2899G>T p.G967C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53608452; called by muse, varscan2
- TGM2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1185984509, COSV63931306; called by muse, mutect2, varscan2
- TMEM219 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as rs200245582; called by muse, mutect2
- TMTC1 | c.515C>A p.A172E (on ENST00000539277 / NM_001193451.2; = p.A64E on NM_175861.3) | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs745920952, COSV55493040; called by muse, mutect2, varscan2
- TRABD2A | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1277559741; called by muse, varscan2
- TRABD2A | c.165C>G p.F55L | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.08); catalogued as COSV100120246; called by muse, varscan2
- TRAPPC8 | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV51974320; called by muse, mutect2, varscan2
- TRAPPC9 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 53/447 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.042); catalogued as rs1357437109; called by muse, mutect2, varscan2
- TRDMT1 | c.252-1G>T p.X84_splice | Splice Site (SNP) | VAF 42/142 reads (30%) | catalogued as rs1307397729, COSV58320146; called by muse, varscan2
- TRIM48 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 145/481 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs202054751; called by muse, mutect2, varscan2
- TRIM49 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 47/405 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV100316162; called by muse, mutect2, varscan2
- TSHZ1 | c.2602G>C p.D868H (on ENST00000580243 / NM_001308210.2; = p.D823H on NM_005786.6) | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100433398, COSV59012126; called by muse, mutect2, varscan2
- TSNARE1 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56183630; called by muse, mutect2, varscan2
- TTLL7 | c.2623C>A p.R875S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.199); catalogued as rs764177870; called by muse, mutect2, varscan2
- TUBB8B | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as rs1397912884; called by muse, varscan2
- UGT1A10 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); catalogued as rs756885476, COSV60832577; called by muse, mutect2
- UROC1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.267); catalogued as COSV104393381; called by muse, mutect2
- USF3 | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100325628; called by muse, mutect2, varscan2
- USP40 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs754906656, COSV52477286; called by muse, mutect2, varscan2
- VPS13B | c.5912G>T p.R1971I | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100660518; called by muse, mutect2, varscan2
- VRK2 | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs1440759470; called by muse, mutect2, varscan2
- VSIG4 | c.1004G>T p.R335M | Missense Mutation (SNP) | VAF 115/181 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs371841595; called by muse, mutect2, varscan2
- VSTM2L | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs751853698, COSV65095568; called by muse, mutect2, varscan2
- VWA5B2 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1158407078; called by muse, mutect2, varscan2
- VWDE | c.2564T>A p.V855E | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99280349; called by muse, mutect2, varscan2
- WASHC5 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs1159762463, COSV59195477; called by muse, mutect2, varscan2
- WASHC5 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100572960; called by muse, mutect2, varscan2
- WWC2 | c.3541A>T p.K1181* | Nonsense Mutation (SNP) | VAF 24/162 reads (15%) | catalogued as rs779829656; called by muse, mutect2, varscan2
- XKR6 | c.840G>C p.M280I | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58654520; called by muse, mutect2, varscan2
- YLPM1 | c.3853G>T p.D1285Y | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV99460107; called by muse, mutect2, varscan2
- ZC2HC1B | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs966004980; called by muse, mutect2, varscan2
- ZDBF2 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV65627449; called by muse, mutect2, varscan2
- ZFHX4 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50927048, COSV51477020; called by muse, mutect2, varscan2
- ZIC1 | c.830C>G p.P277R | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV51555799; called by muse, mutect2, varscan2
- ZNF100 | c.323-1G>T p.X108_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV59750029; called by muse, mutect2, varscan2
- ZNF135 | c.1394C>A p.P465H (on ENST00000313434 / NM_001289401.2; = p.P477H on NM_003436.4) | Missense Mutation (SNP) | VAF 105/413 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100536568; called by muse, mutect2, varscan2
- ZNF223 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101462602; called by muse, mutect2, varscan2
- ZNF264 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54042593; called by muse, varscan2
- ZNF536 | c.3809C>A p.A1270D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs766906828, COSV62836005; called by muse, mutect2
- ZNF676 | c.670A>T p.T224S (on ENST00000650058; = p.T192S on NM_001001411.3) | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV68095023; called by muse, varscan2
- ZNF678 | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438278143; called by muse, mutect2, varscan2
- ZNF793 | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71325231; called by muse, mutect2, varscan2
- ZNF835 | c.1004C>A p.A335E | Missense Mutation (SNP) | VAF 94/383 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV101606268, COSV73379314; called by muse, mutect2, varscan2
- ZNF875 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60990367; called by muse, mutect2, varscan2
- ZP4 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs767172203; called by muse, mutect2, varscan2
- AC025165.3 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC068580.4 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AC134980.2 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.392); called by mutect2, varscan2
- ACE | c.2269T>C p.C757R | Missense Mutation (SNP) | VAF 114/409 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACLY | c.2536G>T p.D846Y | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ACLY | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACOX1 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 94/430 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSBG2 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ACSM6 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ACSS1 | c.91del p.V31* | Frame Shift Del (DEL) | VAF 36/239 reads (15%) | called by pindel, varscan2*
- ADAM20 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS1 | c.2437A>T p.S813C | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTS10 | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4977C>A p.C1659* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- ADARB2 | c.188-1G>T p.X63_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- ADCY1 | c.2933-2A>C p.X978_splice | Splice Site (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- ADCY1 | c.2933-1G>T p.X978_splice | Splice Site (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- ADD2 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADGRB3 | c.3874G>T p.A1292S | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.2098A>T p.R700* (on ENST00000506720 / NM_001322402.2; = p.R632* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 22/214 reads (10%) | called by muse, varscan2
- AFG3L2 | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- AFMID | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- AGBL1 | c.1922A>T p.Q641L | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- AGO2 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- AGO4 | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGPAT2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AHDC1 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- AHDC1 | c.59A>C p.D20A | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- AHNAK2 | c.15857G>T p.G5286V | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- AK3 | c.191A>T p.K64I | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ALDH1A1 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMTN | c.297G>T p.V99= | Splice Region (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- AMZ2 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 68/438 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANK2 | c.5212G>T p.G1738C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANK2 | c.6739C>A p.L2247I | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK2 | c.7751C>A p.P2584H | Missense Mutation (SNP) | VAF 53/404 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.7998T>A p.S2666R | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK2 | c.9523G>A p.V3175M | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANK3 | c.8530A>G p.R2844G | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD12 | c.3833C>G p.A1278G | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ANKRD36 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKRD53 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANKS1B | c.811T>C p.S271P | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANLN | c.69G>T p.M23I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANTXRL | c.1166C>A p.P389Q | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- APOB | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 117/468 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOBEC4 | c.672C>A p.H224Q | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APOBR | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- APOOL | c.690A>T p.E230D | Missense Mutation (SNP) | VAF 86/148 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ARFGEF3 | c.6490G>A p.E2164K | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ARGFX | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP12 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARHGAP32 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ARHGAP6 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2
- ARHGEF28 | c.4708G>T p.A1570S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2
- ARID3B | c.1234C>G p.Q412E | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ARID5B | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARPC5L | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ARSF | c.831-1G>T p.X277_splice | Splice Site (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2
- ARSF | c.1550C>A p.T517K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ASPM | c.1334A>T p.K445I | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ASXL3 | c.6577G>T p.A2193S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ATF7IP | c.1935G>T p.K645N | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATG5 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ATP2C1 | c.736A>T p.K246* | Nonsense Mutation (SNP) | VAF 30/259 reads (12%) | called by muse, mutect2, varscan2
- ATRN | c.4249C>G p.R1417G | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AURKC | c.260A>T p.Q87L (on ENST00000302804 / NM_001015878.2; = p.Q53L on NM_003160.3) | Missense Mutation (SNP) | VAF 137/499 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- AVPR1B | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AXDND1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- B3GAT1 | c.699C>A p.N233K | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- B4GALNT4 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- BCR | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- BEND3 | c.2095T>C p.C699R | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BICC1 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3565G>T p.E1189* | Nonsense Mutation (SNP) | VAF 36/253 reads (14%) | called by muse, mutect2, varscan2
- BNIP5 | c.1706_1711dup p.F570_S571ins* | Nonsense Mutation (INS) | VAF 22/144 reads (15%) | called by mutect2, pindel
- BPTF | c.7932G>C p.Q2644H | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BRCA2 | c.1277A>T p.K426I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BRSK2 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BSN | c.6560T>C p.V2187A | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- BUB1 | c.2862A>T p.K954N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- C2CD4C | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- C6orf132 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CA1 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CA13 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1B | c.765dup p.N256Qfs*10 | Frame Shift Ins (INS) | VAF 15/150 reads (10%) | called by pindel, varscan2
- CALD1 | c.2221G>A p.G741R (on ENST00000361675 / NM_033138.4; = p.G486R on NM_004342.7) | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALHM1 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CALN1 | c.79A>T p.S27C (on ENST00000329008 / NM_001017440.3; = p.S69C on NM_031468.4) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CARD11 | c.1229T>C p.L410P | Missense Mutation (SNP) | VAF 131/523 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBLN1 | c.222del p.S75Pfs*3 | Frame Shift Del (DEL) | VAF 68/226 reads (30%) | called by mutect2, pindel*, varscan2
- CCDC168 | c.9775C>T p.Q3259* | Nonsense Mutation (SNP) | VAF 24/163 reads (15%) | called by muse, mutect2, varscan2
- CCDC178 | c.1210A>T p.T404S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC63 | c.1093C>G p.R365G | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CCKAR | c.1061T>A p.F354Y | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CCN6 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 84/525 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CCNL2 | c.651G>C p.Q217H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCSER1 | c.1062A>T p.E354D | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD34 | c.78G>A p.L26= | Splice Region (SNP) | VAF 183/438 reads (42%) | called by muse, mutect2, varscan2
- CD4 | c.497_498del p.G166Efs*13 | Frame Shift Del (DEL) | VAF 206/493 reads (42%) | called by mutect2, pindel, varscan2
- CD44 | c.1955T>C p.I652T | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDH24 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CDK2AP2 | c.369C>A p.N123K | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CDR1 | c.281dup p.L94Ffs*36 | Frame Shift Ins (INS) | VAF 75/164 reads (46%) | called by mutect2, pindel, varscan2
- CDX1 | c.200C>G p.A67G | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CECR2 | c.1221A>T p.Q407H (on ENST00000342247 / NM_001290047.2; = p.Q224H on NM_001290046.1) | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CENPP | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- CEP295NL | c.1221G>C p.R407S | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CEP350 | c.8325A>T p.K2775N | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CEP72 | c.1075G>T p.G359W | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CFAP46 | c.6982G>T p.V2328F | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- CFAP91 | c.1422A>T p.Q474H | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CHAC1 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 152/386 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD1L | c.1265G>T p.R422M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CHD6 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- CHD8 | c.5852_5856del p.Q1951Pfs*54 (on ENST00000646647 / NM_001170629.2; = p.Q1672Pfs*54 on NM_020920.4) | Frame Shift Del (DEL) | VAF 56/197 reads (28%) | called by mutect2, pindel, varscan2
- CHRD | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 78/433 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHRNA6 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST15 | c.1469A>G p.H490R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CIB4 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- CKAP2L | c.1564A>T p.N522Y | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- CLASP1 | c.569G>T p.S190I | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CLCNKA | c.1482G>C p.Q494H | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CLDN14 | c.597G>T p.R199S | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC12A | c.409T>C p.W137R | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CLEC14A | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CLEC1B | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLINT1 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 124/503 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CLVS2 | c.472T>A p.F158I | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- CNBD1 | c.1082A>T p.Y361F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CNBD1 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- CNTN3 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COG3 | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- COL16A1 | c.2416-1G>T p.X806_splice | Splice Site (SNP) | VAF 40/241 reads (17%) | called by muse, mutect2, varscan2
- COL23A1 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- COL24A1 | c.3443G>C p.R1148T | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL25A1 | c.1198-2A>T p.X400_splice | Splice Site (SNP) | VAF 69/227 reads (30%) | called by muse, mutect2, varscan2
- COL3A1 | c.1608+2T>C p.X536_splice | Splice Site (SNP) | VAF 78/215 reads (36%) | called by muse, mutect2, varscan2
- COL3A1 | c.3497G>C p.R1166P | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A1 | c.4519G>T p.G1507C | Missense Mutation (SNP) | VAF 83/449 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.2063A>T p.Q688L | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- COL7A1 | c.5180A>G p.E1727G | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- COPB2 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 27/264 reads (10%) | called by muse, mutect2, varscan2
- COQ10A | c.553C>G p.R185G | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2
- CPA1 | c.1232T>A p.M411K | Missense Mutation (SNP) | VAF 164/495 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- CPB1 | c.1208T>A p.L403Q | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CPD | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.803); called by muse, varscan2
- CPM | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CPS1 | c.4503G>C p.*1501Yext*13 | Nonstop Mutation (SNP) | VAF 45/419 reads (11%) | called by muse, varscan2
- CPSF4L | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CRB1 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CROCC2 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CSMD1 | c.4848C>A p.D1616E (on ENST00000520002; = p.D1615E on NM_033225.6) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2
- CSMD1 | c.2339A>T p.K780M (on ENST00000520002; = p.K779M on NM_033225.6) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD1 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD2 | c.9719G>T p.G3240V | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTCFL | c.509C>A p.A170E | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.519); called by muse, mutect2
- CUX2 | c.3470G>T p.C1157F | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CXorf56 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP20A1 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 15/164 reads (9%) | called by muse, mutect2
- CYP27C1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CYP4F22 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 110/532 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYTH2 | c.1192G>C p.E398Q (on ENST00000427476; = p.E397Q on NM_004228.7) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- DAB2IP | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- DACH1 | c.965-2A>T p.X322_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- DAGLA | c.1228C>G p.L410V | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCP1B | c.641A>T p.Q214L | Missense Mutation (SNP) | VAF 92/174 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX11 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 121/1208 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, varscan2
- DDX43 | c.1174T>A p.Y392N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX47 | c.981G>T p.L327F | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX60 | c.3648G>T p.K1216N | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DEFB115 | c.176G>T p.C59F | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DEFB121 | c.90C>A p.C30* | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2
- DHX30 | c.3332-1G>A p.X1111_splice (on ENST00000445061 / NM_138615.3; = p.X1072_splice on NM_014966.3) | Splice Site (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- DISC1 | c.142A>T p.S48C | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DLK1 | c.1124G>T p.S375I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DLX5 | c.465G>T p.R155S | Missense Mutation (SNP) | VAF 99/846 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DMRT2 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DNAH10 | c.6194T>C p.F2065S (on ENST00000409039; = p.F2004S on NM_207437.3) | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DNAH12 | c.8831C>G p.S2944* (on ENST00000351747; = p.S3812* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 30/184 reads (16%) | called by muse, mutect2, varscan2
- DNAH6 | c.3476-2A>T p.X1159_splice | Splice Site (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- DNASE2B | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNMT3A | c.1142_1143del p.G381Efs*11 | Frame Shift Del (DEL) | VAF 27/187 reads (14%) | called by mutect2, pindel, varscan2
- DOCK2 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DPP10 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 72/222 reads (32%) | called by muse, mutect2, varscan2
- DSPP | c.3168T>A p.N1056K | Missense Mutation (SNP) | VAF 107/920 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, varscan2
- DSPP | c.3366T>A p.N1122K | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, varscan2
- DTNBP1 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP8 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- DYRK3 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DYSF | c.4294C>A p.P1432T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- DYSF | c.5582T>C p.L1861P | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- E4F1 | c.2016G>A p.M672I | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- EDC3 | c.164G>T p.R55M | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- EHD1 | c.1295A>T p.E432V | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EIF2AK2 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2
- EIF2S3B | c.1135A>T p.R379* | Nonsense Mutation (SNP) | VAF 74/511 reads (14%) | called by muse, mutect2, varscan2
- EIF3A | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- EIF3F | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ELK4 | c.110A>C p.Q37P | Missense Mutation (SNP) | VAF 188/429 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EML4 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENAM | c.1756C>A p.H586N | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ENTPD6 | c.619T>C p.S207P | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- EPB41L2 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ERICH3 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- ERICH6B | c.1189C>A p.L397M | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ESPNL | c.2728G>T p.A910S | Missense Mutation (SNP) | VAF 156/374 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ETHE1 | c.527A>T p.H176L | Missense Mutation (SNP) | VAF 73/682 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- EXOC4 | c.764-1G>T p.X255_splice | Splice Site (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- EYA1 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EYS | c.4786T>G p.W1596G | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- F2RL2 | c.987C>G p.Y329* | Nonsense Mutation (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- FAM124B | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM186A | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FAM214B | c.5G>C p.R2P | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM234A | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FAR1 | c.1486G>T p.V496L | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FAT2 | c.7709C>A p.T2570K | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FAT3 | c.10219G>T p.E3407* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- FBN2 | c.6226C>A p.P2076T | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FBXO41 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); called by muse, mutect2
- FBXO47 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FCGR3B | c.179G>C p.W60S | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FCN1 | c.725del p.G242Afs*7 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by pindel, varscan2
- FCRL5 | c.2040T>A p.C680* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- FCRL5 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- FCRLB | c.622C>A p.R208S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- FDXR | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 38/191 reads (20%) | called by muse, mutect2, varscan2
- FER | c.2398A>T p.K800* | Nonsense Mutation (SNP) | VAF 43/175 reads (25%) | called by muse, mutect2, varscan2
- FER1L6 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 117/311 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGF16 | c.534A>T p.K178N | Missense Mutation (SNP) | VAF 175/281 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- FHOD3 | c.2909A>T p.N970I (on ENST00000359247 / NM_001281739.3; = p.N987I on NM_025135.5) | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG2 | c.4805C>A p.A1602D | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- FLYWCH1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMNL1 | c.404G>T p.W135L | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXJ1 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMD1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FRY | c.7161G>T p.Q2387H | Missense Mutation (SNP) | VAF 79/428 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FSCB | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- FYB2 | c.483C>A p.N161K | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- GABBR1 | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- GABRB1 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GABRG1 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GADL1 | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GADL1 | c.57G>C p.E19D | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALNT15 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GARS1 | c.898A>G p.T300A | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GATA2 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GBA3 | c.619A>T p.S207C | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GBP6 | c.192C>T p.G64= | Splice Region (SNP) | VAF 22/112 reads (20%) | called by muse, varscan2
- GFI1 | c.959G>T p.S320I | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GFOD1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GIMAP1 | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 104/281 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- GIMAP6 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 95/272 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GIPC1 | c.555C>G p.S185R | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GIPC3 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK2 | c.1255C>A p.L419I | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2
- GLB1 | c.1573G>T p.G525W | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- GLE1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- GLI3 | c.2135C>A p.S712* | Nonsense Mutation (SNP) | VAF 93/472 reads (20%) | called by muse, mutect2, varscan2
- GNG2 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- GOLGA6L10 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 84/2154 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.334); called by muse, mutect2
- GOLGA6L10 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 80/1591 reads (5%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.74); called by muse, mutect2
- GPATCH2L | c.1328A>T p.Q443L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GPM6A | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- GPM6A | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, varscan2
- GPR139 | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- GRIA1 | c.803A>T p.Q268L | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- HACE1 | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HACE1 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS1 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HDAC9 | c.1315A>C p.K439Q | Missense Mutation (SNP) | VAF 101/427 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HEATR5B | c.5140G>A p.A1714T | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- HECTD4 | c.10815A>T p.L3605F | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECW2 | c.2689G>C p.D897H | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- HERC5 | c.1425A>T p.K475N | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HIPK2 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HK3 | c.1949G>T p.R650I | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HMCN2 | c.14951C>A p.T4984N | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- HOXB4 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- HTR2A | c.43A>T p.T15S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HTR2C | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTR3A | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IFIT5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IGFBP1 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGFBP1 | c.501del p.N168Tfs*11 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1-5 | c.248G>T p.R83M | Missense Mutation (SNP) | VAF 61/615 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- IGKV6-21 | c.326A>T p.Q109L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by mutect2, varscan2
- IGLV3-21 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IKZF3 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 43/189 reads (23%) | called by muse, mutect2, varscan2
- IL11RA | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 61/547 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IL12RB1 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 60/409 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL1RL1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL1RL2 | c.828A>T p.E276D | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPDH1 | c.703G>T p.A235S (on ENST00000470772 / NM_001142573.2; = p.A321S on NM_000883.4) | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- INAFM1 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPP5F | c.1727C>G p.S576C | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- INSYN2B | c.777A>C p.L259F | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.235); called by muse, varscan2
- IQCA1 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, varscan2
- IQSEC3 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 33/800 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- IQUB | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IRS2 | c.1775C>G p.S592C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ITGA10 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 45/278 reads (16%) | called by muse, mutect2, varscan2
- ITGA4 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ITGAM | c.998T>C p.F333S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ITGB2 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2
- ITIH2 | c.1826C>A p.T609K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITM2C | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- IZUMO3 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT tolerated (0.17); called by muse, mutect2, varscan2
- KCND2 | c.661T>A p.C221S | Missense Mutation (SNP) | VAF 124/388 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCNF1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- KCNH2 | c.2128G>T p.G710C | Missense Mutation (SNP) | VAF 98/487 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH5 | c.2356C>G p.P786A | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ12 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- KCNK3 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KCNN3 | c.1842A>T p.K614N (on ENST00000618040 / NM_001204087.1; = p.K599N on NM_002249.6) | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KCNT1 | c.2786G>C p.R929T (on ENST00000488444; = p.R948T on NM_020822.3) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNT2 | c.2910+1G>T p.X970_splice | Splice Site (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- KCNT2 | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNT2 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2
- KCTD16 | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIAA1210 | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 95/174 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- KIF11 | c.1129-2A>T p.X377_splice | Splice Site (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- KIF17 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF20B | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF20B | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF5A | c.2044C>A p.L682M | Missense Mutation (SNP) | VAF 113/505 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.125); called by mutect2, varscan2
- KIF5A | c.2048dup p.D684Gfs*5 | Frame Shift Ins (INS) | VAF 105/534 reads (20%) | called by mutect2, pindel, varscan2
- KIZ | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KLHL24 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 88/221 reads (40%) | called by muse, mutect2, varscan2
- KLHL35 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KLHL42 | c.732G>C p.R244S | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- KLK15 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KMT2D | c.9059A>C p.K3020T | Missense Mutation (SNP) | VAF 131/491 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT5B | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPRP | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.451); called by muse, varscan2
- KPRP | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- KRT34 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KRT39 | c.902G>T p.S301I | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT40 | c.450C>G p.I150M | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KRT82 | c.778-2A>T p.X260_splice | Splice Site (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2
- KRTAP10-9 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 69/465 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRTAP5-3 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- L1CAM | c.207G>C p.W69C | Missense Mutation (SNP) | VAF 164/296 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L3MBTL3 | c.2001G>T p.Q667H | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- LAMB2 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- LCK | c.1087C>A p.R363S | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- LCK | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 64/432 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LCMT1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LDLRAD4 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LENG8 | c.1550A>G p.Q517R | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- LEO1 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2
- LGALSL | c.518G>T p.*173Lext*16 | Nonstop Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- LGR4 | c.2556G>T p.Q852H | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIFR | c.3058G>T p.E1020* | Nonsense Mutation (SNP) | VAF 42/428 reads (10%) | called by muse, mutect2, varscan2
- LILRB5 | c.1475-8C>T | Splice Region (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- LIM2 | c.176C>G p.A59G (on ENST00000596399 / NM_001161748.2; = p.A101G on NM_030657.4) | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- LIPG | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 135/436 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMO2 | c.55G>T p.E19* (on ENST00000395833 / NM_001142315.2; = p.E88* on NM_005574.4) | Nonsense Mutation (SNP) | VAF 55/399 reads (14%) | called by muse, mutect2, varscan2
- LOXL2 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LRP1 | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 104/472 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC43 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 43/266 reads (16%) | called by muse, mutect2, varscan2
- LRRC4B | c.2081T>G p.I694S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, varscan2
- LRRC7 | c.2032G>T p.G678W (on ENST00000651989 / NM_001370785.2; = p.G645W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC7 | c.3314C>A p.A1105D (on ENST00000651989 / NM_001370785.2; = p.A1072D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- LRRC8D | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- LRRC9 | c.1289A>C p.K430T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LRRN1 | c.2129C>A p.S710Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by mutect2, varscan2
- LSAMP | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LTBP1 | c.1559A>T p.Q520L (on ENST00000404816 / NM_206943.4; = p.Q194L on NM_000627.4) | Missense Mutation (SNP) | VAF 70/504 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LY75 | c.1981C>T p.H661Y | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- LYZL2 | c.501A>T p.Q167H (on ENST00000375318; = p.Q121H on NM_183058.3) | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAGEB16 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- MAGI1 | c.1949del p.P650Qfs*19 | Frame Shift Del (DEL) | VAF 38/277 reads (14%) | called by mutect2, pindel, varscan2
- MAPK11 | c.545A>T p.Y182F | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- MAST4 | c.4977del p.K1660Rfs*20 (on ENST00000403625 / NM_001164664.2; = p.K1471Rfs*20 on NM_015183.3) | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- MATR3 | c.2372-1G>T p.X791_splice | Splice Site (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- MCM10 | c.882G>T p.W294C (on ENST00000484800 / NM_182751.3; = p.W293C on NM_018518.5) | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ME3 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- MET | c.3943G>T p.V1315L | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- METTL25 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MGAM2 | c.6158G>A p.S2053N | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2, varscan2
- MICAL3 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP2 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MNDA | c.464A>T p.Q155L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MRC1 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MS4A12 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MS4A3 | c.502T>A p.S168T | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- MUC16 | c.27092C>G p.T9031R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- MUC16 | c.26731A>T p.S8911C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); called by muse, varscan2
- MUC16 | c.8386G>T p.A2796S | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MUC5AC | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- MUC5AC | c.566G>T p.W189L | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC5B | c.13889C>A p.P4630H | Missense Mutation (SNP) | VAF 195/627 reads (31%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.562); called by muse, varscan2
- MUS81 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MYH11 | c.3628G>T p.E1210* | Nonsense Mutation (SNP) | VAF 56/465 reads (12%) | called by muse, mutect2, varscan2
- MYH13 | c.1875C>G p.N625K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MYH14 | c.2540G>T p.R847I | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO7B | c.2779G>T p.G927W | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYOM3 | c.472A>T p.I158F | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MYT1L | c.1659C>A p.C553* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- NAV3 | c.780C>A p.S260R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NCKAP5 | c.5090A>T p.D1697V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NCOR2 | c.5026A>T p.T1676S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- NDRG2 | c.1028G>T p.R343L (on ENST00000298687 / NM_001354570.1; = p.R329L on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEBL | c.2056-1G>C p.X686_splice | Splice Site (SNP) | VAF 63/256 reads (25%) | called by muse, mutect2, varscan2
- NEFL | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEU4 | c.458-1G>T p.X153_splice (on ENST00000391969 / NM_001167602.3; = p.X165_splice on NM_080741.4) | Splice Site (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- NEURL1 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEURL1 | c.1342T>A p.S448T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- NFATC2 | c.1906-2A>C p.X636_splice | Splice Site (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- NIBAN1 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- NINL | c.3811G>T p.E1271* | Nonsense Mutation (SNP) | VAF 119/495 reads (24%) | called by muse, mutect2, varscan2
- NLRC4 | c.750C>G p.Y250* | Nonsense Mutation (SNP) | VAF 92/312 reads (29%) | called by muse, mutect2, varscan2
- NLRP1 | c.1043A>T p.K348M | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
788 further variants in this file (310 protein-altering or splice-affecting, 291 silent, 187 other) are not listed here.
